EXCEPTIONAL_RESPONDERS case ER-ABNX — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0270f8f8-7861-4fdf-8492-032eb571f91a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Sigmoid colon; Site of resection or biopsy: Sigmoid colon; Classification of tumor: primary; Age at diagnosis: 56.2 years (20,533 days); Year of diagnosis: 2005; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 3,659 days (10.0 years); Days to best overall response: 204 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab + Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 33 days; Days to treatment end: 189 days.

Follow-up (1 entry)
- Days to follow up: 3,659 days (10.0 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 3,659 days (10.0 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABNX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABNX-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 38; Percent tumor nuclei: 10; Percent normal cells: 60; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
